Gene-level copy-number profile of tumor specimen ALCH-B48G-TTP1-A from ALCHEMIST case ALCH-B48G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.9 years (27,708 days).
Specimen ALCH-B48G-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c635c7a-96d0-4cfd-b23b-7b6a5c6b0a3e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B48G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/8d0c83d4-0dd5-43af-aed7-34e64a8f8cae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 473; copy number 2: 56,720; copy number 3: 1,040; copy number 4: 132; copy number 7: 2; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,998,531–129,998,936, 1 gene: AC083906.1.
- chr3:130,081,831–130,113,227, 3 genes (within-gene range 0–2): ALG1L2, LINC02014, FAM86HP.
- chr11:76,190,725–76,195,071, 1 gene (within-gene range 0–2): AP000785.1.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr15:25,199,448–25,229,048, 17 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,092,956–43,107,570, 1 gene, copy number 7: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 7–15: MRPL51P2, FRGCA.

Autosomal genes at a single copy (total copy number 1): 473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
